Gene-level copy-number profile of tumor specimen TCGA-31-1953-01A from TCGA case TCGA-31-1953, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 52.2 years (19,064 days).
Specimen TCGA-31-1953-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.ac9b9cbc-04ee-47e8-aaf3-9166bb74b52a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-31-1953-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4fe97b8a-bac7-440a-98e1-490c39059563

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 83; copy number 2: 10,615; copy number 3: 17,516; copy number 4: 22,140; copy number 5: 4,792; copy number 6: 3,428; copy number 7: 481; copy number 8: 511; copy number 9: 145; copy number 10: 97; copy number 11: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-31-1953-01A-01D-0648-01): tumor purity 0.64, ploidy 3.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:86,725,500–86,726,053, 1 gene: TXNL1P1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 243 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,974,757–61,462,788, 9 genes, copy number 9 (within-gene range 6–9): RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1.
- chr1:150,067,279–150,809,577, 35 genes, copy number 10: VPS45, PLEKHO1, AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1, CTSK, UBE2D3P3.
- chr1:150,812,591–150,812,698, 1 gene, copy number 10: RNU6-1309P.
- chr1:172,138,397–172,213,499, 5 genes, copy number 9: DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1.
- chr2:190,189,735–193,257,757, 39 genes, copy number 9 (within-gene range 6–9): HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P, NABP1, AC114778.1, NABP1-OT1, AC098872.1, CAVIN2, CAVIN2-AS1, DNAJB1P1, TMEFF2, AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2, AC096647.1, SLC44A3P1.
- chr2:195,448,532–196,593,684, 16 genes, copy number 9 (within-gene range 4–9): AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P.
- chr3:133,824,235–137,536,142, 49 genes, copy number 10 (within-gene range 8–10): RAB6B, C3orf36, SLCO2A1, LINC02000, RYK, HMGB3P14, LINC02004, AC010207.1, RPL39P5, AMOTL2, MIR6827, HMGN1P9, HMGB3P13, MIR4788, ANAPC13, CEP63, AC026117.1, EPHB1, KY, AC016931.1, RNU6-1174P, RNA5SP141, AC092969.1, AC092989.1, NDUFS6P1, PPP2R3A, AC072039.1, AC072039.2, MSL2, TDGF1P6, AC092991.1, PCCB, STAG1, RNU6-1284P, HMGN1P10, RNU6-789P, AC117382.1, AC117382.2, AC096992.3, AC096992.1, SLC35G2, NCK1-DT, AC096992.2, NCK1, RAD51AP1P1, IL20RB, IL20RB-AS1, RNA5SP142, AC117440.1.
- chr3:168,902,194–172,604,006, 76 genes, copy number 9 (broad region; genes not listed).
- chr10:24,481,180–24,483,034, 1 gene, copy number 11: AL353583.1.
- chr18:12,658,043–13,125,052, 12 genes, copy number 10 (within-gene range 6–10): PSMG2, CEP76, AP005482.2, AP005482.1, LINC01882, Y_RNA, PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192.

Autosomal genes at a single copy (total copy number 1): 83. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
